Somatic mutation profile of tumor specimen TCGA-YH-A8SY-01A (aliquot TCGA-YH-A8SY-01A-11D-A377-08) from TCGA case TCGA-YH-A8SY, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; Tumor grade: G2; Age at diagnosis: 73.5 years (26,859 days).
Specimen TCGA-YH-A8SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d4fc49-5069-4ed6-938f-9016a11658af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YH-A8SY-10A (Blood Derived Normal), aliquot TCGA-YH-A8SY-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7058028-40b4-4ee5-9eff-6a6df5f47904

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 19, Nonsense Mutation 8, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 84/394 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 65/337 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AMER1 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1181603022, COSV100367107; called by muse, mutect2, varscan2
- AMOT | c.1708C>T p.R570* (on ENST00000371959 / NM_001113490.1; = p.R161* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 179/1150 reads (16%) | catalogued as COSV59063802, COSV59066847; called by muse, mutect2, varscan2
- ATP11B | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100018156; called by muse, mutect2, varscan2
- CACNA1D | c.4291G>T p.E1431* (on ENST00000350061 / NM_001128840.3; = p.E1451* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 26/643 reads (4%) | catalogued as COSV99860212; called by muse, mutect2
- CAPN3 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 85/545 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as rs375279877, CD1411775; called by muse, mutect2, varscan2
- CLSTN2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs137889465; called by muse, mutect2, varscan2
- COL28A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs748651915, COSV68081043; called by muse, mutect2, varscan2
- DOP1B | c.1920G>T p.K640N | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV101215377; called by muse, mutect2, varscan2
- ELAVL4 | c.251-2A>G p.X84_splice | Splice Site (SNP) | VAF 21/202 reads (10%) | catalogued as COSV100836930, COSV63919420; called by muse, mutect2, varscan2
- EPHA5 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs756849899, COSV56656014; called by muse, mutect2, varscan2
- FLNA | c.1832T>C p.F611S | Missense Mutation (SNP) | VAF 66/454 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100775306; called by muse, mutect2, varscan2
- FRMPD4 | c.152T>C p.F51S | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV101044207; called by muse, varscan2
- GFPT2 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 188/1015 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs779641006, COSV53807357, COSV99518142; called by muse, mutect2, varscan2
- HK3 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs190052913, COSV52836623; called by muse, mutect2, varscan2
- HOXB5 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1448900570, COSV99494775; called by muse, mutect2
- KRTAP11-1 | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV100190855; called by muse, mutect2, varscan2
- MECR | c.274G>T p.G92* | Nonsense Mutation (SNP) | VAF 187/977 reads (19%) | catalogued as rs773845755, COSV99747439; called by muse, mutect2, varscan2
- MTSS2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as rs1371183635, COSV100116722; called by muse, mutect2
- NGF | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 26/178 reads (15%) | catalogued as COSV65687395; called by muse, mutect2, varscan2
- NINL | c.3628C>T p.Q1210* | Nonsense Mutation (SNP) | VAF 67/354 reads (19%) | catalogued as rs200555815, COSV99626448; called by muse, mutect2, varscan2
- NKRF | c.130A>T p.K44* | Nonsense Mutation (SNP) | VAF 114/648 reads (18%) | catalogued as COSV100441923; called by muse, mutect2, varscan2
- OR51E1 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211566; called by muse, mutect2
- PCDH17 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV64976714; called by muse, mutect2, varscan2
- PCDHB3 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 37/535 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.069); catalogued as rs558026324, COSV50571674; called by muse, mutect2
- PLEC | c.10303C>A p.L3435M (on ENST00000322810 / NM_201380.4; = p.L3325M on NM_000445.5) | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100519561; called by muse, mutect2, varscan2
- PXDN | c.4051A>T p.T1351S | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99415109; called by muse, mutect2
- RYR3 | c.8111G>T p.R2704L (on ENST00000389232; = p.R2705L on NM_001036.6) | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101214816, COSV66787150; called by muse, mutect2, varscan2
- SEMA3E | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs373711827, COSV57088111; called by muse, mutect2, varscan2
- STK40 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs372595502; called by muse, mutect2, varscan2
- SYT2 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 60/529 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100937218; called by muse, mutect2, varscan2
- TLX2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760313591, COSV99283797; called by muse, mutect2, varscan2
- UPK1B | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV99953841; called by muse, mutect2, varscan2
- USH2A | c.9677G>A p.R3226Q | Missense Mutation (SNP) | VAF 107/494 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.138); catalogued as rs1338539009, COSV100243242; called by muse, mutect2, varscan2
- WEE2 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 128/708 reads (18%) | catalogued as rs754062320, COSV101285229; called by muse, mutect2, varscan2
- NDST3 | c.816del p.F272Lfs*5 | Frame Shift Del (DEL) | VAF 108/724 reads (15%) | called by mutect2, varscan2
- ANKRD11 | c.5601C>T p.C1867= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs764304487, COSV99970733; called by muse, mutect2
- ATP1A3 | c.3012C>T p.Y1004= (on ENST00000545399 / NM_001256214.2; = p.Y991= on NM_152296.5) | Silent (SNP) | VAF 41/208 reads (20%) | catalogued as rs372919447; called by muse, mutect2, varscan2
- CREBBP | c.2406C>T p.S802= | Silent (SNP) | VAF 58/281 reads (21%) | catalogued as rs748195458, COSV99270594; called by muse, mutect2, varscan2
- DPYSL5 | c.561C>T p.I187= | Silent (SNP) | VAF 57/236 reads (24%) | catalogued as rs761595322, COSV99982845; called by muse, mutect2, varscan2
- FGFR1 | c.957C>T p.T319= (on ENST00000447712 / NM_023110.3; = p.T317= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as rs767160151, COSV58335139; called by muse, mutect2
- HFM1 | c.3735A>T p.G1245= | Silent (SNP) | VAF 70/784 reads (9%) | catalogued as COSV99646934; called by muse, mutect2
- HTR1A | c.243C>T p.T81= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs759683584, COSV60500102; called by muse, mutect2, varscan2
- KCNC1 | c.498C>T p.G166= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs1434789904, COSV56398949; called by muse, mutect2, varscan2
- KLHDC7A | c.1869C>T p.F623= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs1397426862, COSV68769610; called by muse, varscan2
- KRTAP8-1 | c.174G>A p.S58= | Silent (SNP) | VAF 78/457 reads (17%) | catalogued as rs768734553, COSV100297815, COSV100297871; called by muse, mutect2, varscan2
- MAGEB6B | c.168T>A p.S56= | Silent (SNP) | VAF 106/709 reads (15%) | called by muse, mutect2, varscan2
- OGDHL | c.75G>A p.P25= | Silent (SNP) | VAF 45/257 reads (18%) | catalogued as rs149391137, COSV65104870; called by muse, mutect2, varscan2
- PCDH8 | c.2052C>T p.R684= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs1211542106, COSV100132083, COSV100132141; called by muse, mutect2, varscan2
- PCDHGA1 | c.1926C>T p.L642= | Silent (SNP) | VAF 30/356 reads (8%) | catalogued as COSV65294783; called by muse, mutect2
- TFDP3 | c.405C>T p.G135= | Silent (SNP) | VAF 77/438 reads (18%) | catalogued as rs369336277, COSV59536697; called by muse, mutect2, varscan2
- TIGD4 | c.864G>A p.E288= | Silent (SNP) | VAF 97/611 reads (16%) | catalogued as COSV100428081; called by muse, mutect2, varscan2
- UTP4 | c.1629C>T p.I543= | Silent (SNP) | VAF 60/674 reads (9%) | catalogued as rs554592005, COSV100077188; called by muse, mutect2
- VWA2 | c.1389C>T p.G463= | Silent (SNP) | VAF 42/325 reads (13%) | catalogued as rs1239223627, COSV100074008; called by muse, mutect2, varscan2
- ZFHX4 | c.1581G>A p.A527= | Silent (SNP) | VAF 29/281 reads (10%) | catalogued as COSV99268282; called by muse, mutect2, varscan2
- SV2C | c.581-20774G>T | Intron (SNP) | VAF 74/447 reads (17%) | called by muse, mutect2, varscan2
